Somatic mutation profile of tumor specimen TCGA-58-8392-01A (aliquot TCGA-58-8392-01A-11D-2323-08) from TCGA case TCGA-58-8392, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.4 years (25,710 days).
Specimen TCGA-58-8392-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b3feb80-47a1-43fb-b064-8b21eb0d8e13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8392-10A (Blood Derived Normal), aliquot TCGA-58-8392-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8e0d132-aafd-4cba-a69e-25188a1fdd79

The open-access MAF lists 167 somatic variants for this specimen: 121 protein-altering or splice-affecting, 46 silent.
By variant classification: Missense Mutation 110, Silent 46, Nonsense Mutation 9, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.635-2A>C p.X212_splice | Splice Site (SNP) | VAF 22/74 reads (30%) | hotspot (GDC flag); catalogued as COSV104426442, COSV64288525, COSV64298046; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 35/47 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.4559C>A p.P1520H | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61273027; called by muse, mutect2, varscan2
- ADAMTS12 | c.4558C>A p.P1520T | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61261395; called by muse, mutect2, varscan2
- AMPH | c.1650C>G p.N550K | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV57748990; called by muse, mutect2, varscan2
- ANKLE1 | c.683C>T p.P228L (on ENST00000394458; = p.P174L on NM_152363.6) | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100845687; called by muse, mutect2, varscan2
- CLCN4 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1366141307; called by muse, mutect2, varscan2
- CR2 | c.2335T>G p.C779G | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65510140; called by muse, mutect2, varscan2
- DNAH9 | c.6944C>A p.T2315N | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs563753086; called by muse, mutect2, varscan2
- EMC2 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs536838549, COSV99624003; called by muse, mutect2, varscan2
- FCGBP | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1166578673; called by muse, mutect2
- FNDC3B | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 139/154 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs928979353; called by muse, mutect2, varscan2
- GAD2 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV99394024; called by muse, mutect2
- GJD2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as COSV99290619; called by muse, mutect2, varscan2
- GLIS3 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1174313043; called by muse, mutect2, varscan2
- GPHN | c.1684A>G p.I562V (on ENST00000315266 / NM_001377519.1; = p.I595V on NM_020806.5) | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV100016893; called by muse, mutect2, varscan2
- GYS2 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99680406; called by muse, mutect2, varscan2
- H2AC1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.965); catalogued as COSV51236684; called by muse, mutect2, varscan2
- HCN1 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1348079874, COSV57514141; called by muse, mutect2
- HERC2 | c.9193G>T p.D3065Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55325395; called by muse, mutect2, varscan2
- ICE2 | c.1819A>G p.N607D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs755230900; called by muse, mutect2, varscan2
- IGSF21 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1361344677, COSV99244351; called by muse, mutect2, varscan2
- ITIH2 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs139479101; called by muse, mutect2, varscan2
- LARGE1 | c.1116C>G p.D372E | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100504216; called by muse, mutect2
- LHFPL3 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101308866; called by muse, mutect2, varscan2
- MAGI1 | c.3466G>A p.G1156S (on ENST00000402939 / NM_001033057.2; = p.G1185S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 229/361 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770893503, COSV58323884; called by muse, mutect2, varscan2
- MBD1 | c.1754G>T p.R585L (on ENST00000269468 / NM_001323950.1; = p.R483L on NM_002384.2) | Missense Mutation (SNP) | VAF 115/305 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs147372202; called by muse, mutect2, varscan2
- NETO2 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as rs537560419, COSV57455852; called by muse, mutect2, varscan2
- NOP56 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.027); catalogued as rs144187608; called by muse, mutect2, varscan2
- OR1C1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as rs767980381, COSV68715320; called by muse, mutect2, varscan2
- OTX2 | c.572G>A p.G191D (on ENST00000408990 / NM_172337.3; = p.G199D on NM_021728.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV59767485; called by muse, mutect2, varscan2
- PATL1 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs373828690; called by muse, mutect2, varscan2
- PLEKHG1 | c.2071G>T p.V691F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs368875530; called by muse, mutect2, varscan2
- PPP1R10 | c.1009T>C p.S337P | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs767958910; called by muse, mutect2
- PRPF3 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 15/304 reads (5%) | catalogued as COSV61394005; called by muse, mutect2
- PTEN | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as rs786204854, CM004280, CM124222, COSV100909550, COSV64289957, COSV64297290; called by muse, mutect2, varscan2
- PTPDC1 | c.901G>C p.E301Q (on ENST00000375360 / NM_177995.3; = p.E353Q on NM_152422.4) | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV99997564; called by muse, mutect2, varscan2
- REV3L | c.3580C>T p.R1194* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs1417729268, COSV62615312; called by muse, mutect2, varscan2
- RPS6KC1 | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777557634, COSV65300801; called by muse, mutect2, varscan2
- SACS | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99063619; called by muse, mutect2, varscan2
- SPATA32 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 98/120 reads (82%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs142659640; called by muse, mutect2, varscan2
- SYNGR3 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV99937006; called by muse, mutect2, varscan2
- TAF15 | c.1300G>A p.G434S (on ENST00000605844 / NM_139215.3; = p.G431S on NM_003487.4) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs766057799; called by muse, mutect2
- TRAV8-7 | c.122A>G p.N41S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.172); catalogued as rs1158459986; called by muse, mutect2, varscan2
- TTN | c.10463C>A p.P3488Q (on ENST00000591111; = p.P3442Q on NM_003319.4) | Missense Mutation (SNP) | VAF 25/34 reads (74%) | catalogued as COSV100605019; called by muse, mutect2, varscan2
- WSCD2 | c.619T>A p.C207S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1386626560; called by mutect2, varscan2
- ZFHX4 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs1337712812, COSV50864195; called by muse, mutect2, varscan2
- ZFPM2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.084); catalogued as COSV65872531; called by muse, mutect2, varscan2
- ZNF106 | c.2357G>T p.R786L | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753327485; called by muse, mutect2, varscan2
- ZNF280A | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs753570458; called by muse, mutect2, varscan2
- ZNF418 | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs755294452; called by muse, mutect2, varscan2
- ZNF804B | c.2189G>T p.R730I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV60828370; called by muse, mutect2, varscan2
- ACAN | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL4 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGBL1 | c.3297G>T p.K1099N | Missense Mutation (SNP) | VAF 65/213 reads (31%) | PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK2 | c.7090C>A p.Q2364K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD17 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ARID4A | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP10A | c.2582C>A p.T861N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD5 | c.669C>A p.D223E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CDH20 | c.2383G>T p.E795* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- CDYL | c.155A>G p.Q52R | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CKAP5 | c.3605G>C p.S1202T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.9103T>A p.C3035S (on ENST00000297405 / NM_001363185.1; = p.C2866S on NM_052900.3) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CSMD3 | c.3004A>C p.S1002R (on ENST00000297405 / NM_001363185.1; = p.S898R on NM_052900.3) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, varscan2
- DNAH5 | c.8756A>T p.E2919V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DPP6 | c.929G>A p.G310D (on ENST00000377770 / NM_001364500.2; = p.G248D on NM_001936.5) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD2 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 139/206 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FANCI | c.2739G>C p.Q913H (on ENST00000310775 / NM_001376911.1; = p.Q853H on NM_018193.3) | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- FBXO34 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGNL1 | c.1440A>T p.K480N | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GASK1B | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GFI1 | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPHN | c.1784A>T p.H595L (on ENST00000315266 / NM_001377519.1; = p.H628L on NM_020806.5) | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- GRM8 | c.2396C>A p.P799H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAUS3 | c.784A>T p.M262L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HYDIN | c.13057T>C p.Y4353H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IMPG2 | c.2864G>T p.R955I | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ4 | c.758T>A p.I253N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIF5C | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- KLC1 | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL4 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KRTAP10-8 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- LATS1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- LILRB4 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2 | c.5324G>T p.G1775V | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K21 | c.1190A>T p.Q397L | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NAV3 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NAV3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH4 | c.5859G>C p.W1953C | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- NR1H4 | c.1376A>T p.H459L (on ENST00000551379 / NM_001206993.2; = p.H445L on NM_005123.4) | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NRAP | c.3299A>C p.D1100A (on ENST00000359988 / NM_001322945.2; = p.D1065A on NM_006175.4) | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- NUGGC | c.225T>A p.D75E | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NXPH3 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- OR51A7 | c.300A>T p.Q100H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR52W1 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5K4 | c.966A>T p.*322Yext*? | Nonstop Mutation (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- PARP4 | c.3262G>T p.G1088* | Nonsense Mutation (SNP) | VAF 72/173 reads (42%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.1633A>T p.N545Y | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PHRF1 | c.3703G>T p.A1235S (on ENST00000264555 / NM_001286581.2; = p.A1234S on NM_020901.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.079); called by muse, varscan2
- PKM | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PLCB1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLD3 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PTPN3 | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- RAD50 | c.2836G>T p.D946Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SCAF4 | c.758A>G p.Q253R | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- SECISBP2 | c.1163C>G p.S388C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2
- SELP | c.786C>G p.C262W | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3TC1 | c.599T>A p.L200Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SLC26A4 | c.1341G>C p.K447N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMARCD1 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2
- SOX9 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- SPATA31A1 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 172/501 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SYBU | c.1927C>G p.L643V (on ENST00000276646 / NM_001099754.2; = p.L642V on NM_017786.6) | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TNFRSF13B | c.328A>C p.S110R | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TOR1A | c.360C>G p.Y120* | Nonsense Mutation (SNP) | VAF 137/179 reads (77%) | called by muse, mutect2, varscan2
- TRIM32 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRPM7 | c.1164T>A p.H388Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- UNC13C | c.5873T>A p.L1958Q | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYM6 | c.3875C>A p.T1292N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZNF16 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- ABCG8 | c.1644C>T p.A548= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs200018072; called by muse, mutect2, varscan2
- ADAM10 | c.879A>T p.P293= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- ADGRF3 | c.480C>T p.L160= (on ENST00000311519 / NM_001145168.1; = p.L101= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs1257327532; called by muse, mutect2, varscan2
- ATP2A2 | c.1107G>A p.L369= | Silent (SNP) | VAF 88/227 reads (39%) | called by muse, mutect2, varscan2
- BCHE | c.267T>C p.Y89= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- CACNG2 | c.552C>A p.A184= | Silent (SNP) | VAF 143/465 reads (31%) | called by muse, mutect2, varscan2
- CADM2 | c.432G>C p.L144= (on ENST00000407528 / NM_001167674.2; = p.L146= on NM_153184.4) | Silent (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- CDH20 | c.2382G>T p.S794= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV53010393, COSV99406151; called by muse, mutect2, varscan2
- COL5A3 | c.4242G>A p.P1414= | Silent (SNP) | VAF 99/252 reads (39%) | catalogued as rs537422545, COSV99318247; called by muse, mutect2, varscan2
- DIDO1 | c.5247G>A p.P1749= | Silent (SNP) | VAF 65/115 reads (57%) | catalogued as COSV56634263; called by muse, mutect2, varscan2
- ENAM | c.2994G>T p.L998= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs148122591; called by muse, mutect2, varscan2
- ENTPD2 | c.138T>C p.A46= | Silent (SNP) | VAF 138/204 reads (68%) | called by muse, mutect2, varscan2
- ETFDH | c.522A>G p.V174= | Silent (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- FLNC | c.7272C>T p.N2424= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV57952925; called by muse, mutect2, varscan2
- GPR101 | c.285C>A p.L95= | Silent (SNP) | VAF 19/27 reads (70%) | called by muse, mutect2, varscan2
- H4C6 | c.51G>A p.K17= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs757259494; called by muse, mutect2, varscan2
- IARS1 | c.2010C>T p.L670= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1159980403; called by muse, mutect2, varscan2
- ITGAD | c.1947G>A p.G649= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV101210518; called by muse, mutect2, varscan2
- KIF27 | c.2121G>A p.L707= | Silent (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- LRRK2 | c.5535A>G p.Q1845= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs199888180; called by muse, mutect2, varscan2
- LRRN3 | c.199T>C p.L67= | Silent (SNP) | VAF 43/143 reads (30%) | catalogued as rs747217500; called by muse, mutect2, varscan2
- MARCHF10 | c.291A>G p.P97= | Silent (SNP) | VAF 101/133 reads (76%) | called by muse, mutect2, varscan2
- MRC1 | c.2268G>A p.L756= | Silent (SNP) | VAF 109/177 reads (62%) | catalogued as rs970686034; called by muse, mutect2, varscan2
- MUL1 | c.153A>G p.L51= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs765827538; called by muse, mutect2, varscan2
- MYH1 | c.5079G>T p.R1693= | Silent (SNP) | VAF 65/89 reads (73%) | called by muse, mutect2, varscan2
- NFE2L3 | c.1296C>T p.V432= | Silent (SNP) | VAF 6/172 reads (3%) | called by muse, mutect2
- NUP205 | c.2193C>A p.G731= | Silent (SNP) | VAF 142/421 reads (34%) | called by muse, mutect2, varscan2
- ODAPH | c.114G>A p.A38= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as rs199749835; called by muse, mutect2, varscan2
- OR2B6 | c.348C>A p.A116= | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- OR4B1 | c.30G>A p.L10= | Silent (SNP) | VAF 30/93 reads (32%) | called by muse, mutect2, varscan2
- OR51F2 | c.471C>A p.V157= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as COSV59065355; called by muse, mutect2, varscan2
- OR7C2 | c.843C>T p.T281= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV50180347; called by muse, mutect2, varscan2
- PALLD | c.1983C>T p.A661= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV54992599; called by muse, mutect2, varscan2
- RPP40 | c.681G>T p.L227= | Silent (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- RRM1 | c.456G>A p.E152= | Silent (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- RRS1 | c.684C>T p.S228= | Silent (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- SEC61A1 | c.888C>T p.A296= | Silent (SNP) | VAF 19/180 reads (11%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1707C>A p.V569= | Silent (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- SLITRK5 | c.231C>T p.S77= | Silent (SNP) | VAF 87/152 reads (57%) | catalogued as rs757162741; called by muse, mutect2, varscan2
- SSH2 | c.4062G>A p.Q1354= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs1335212735; called by muse, mutect2, varscan2
- SYNPO | c.1170G>A p.P390= (on ENST00000394243 / NM_001166208.2; = p.P146= on NM_007286.6) | Silent (SNP) | VAF 84/142 reads (59%) | catalogued as rs367801557; called by muse, mutect2, varscan2
- TENT5C | c.387C>T p.I129= | Silent (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- TRPM1 | c.1396C>T p.L466= | Silent (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- TYK2 | c.3130C>T p.L1044= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- ZNF205 | c.1215G>A p.S405= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as rs1363536411, COSV54621056; called by muse, mutect2, varscan2
- ZYX | c.33C>G p.S11= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs779343705, COSV59557200; called by muse, mutect2, varscan2
